Somatic mutation profile of tumor specimen MBCProject_2991_T2_WES (aliquot MBCProject_2991_T2_WES_1) from CMI case MBCProject_2991, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 65.1 years (23,767 days).
Specimen MBCProject_2991_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cce17dc-2a7d-43cc-972c-a9512a9490f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2991_SALIVA (Saliva), aliquot MBCProject_2991_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6caa3473-bb57-4d22-9158-d4e08cc89fcf

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 6, Intron 2, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APPBP2 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 53/220 reads (24%) | catalogued as COSV50025753; called by muse, mutect2, varscan2
- ARHGAP4 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1557106257; called by muse, mutect2
- AURKB | c.529A>T p.T177S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV60244870; called by muse, mutect2, varscan2
- CDH1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 61/147 reads (41%) | catalogued as COSV55737768; called by muse, mutect2, varscan2
- FLG2 | c.6225G>T p.Q2075H | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV101165770, COSV66169525; called by muse, mutect2, varscan2
- IRX2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1349932792, COSV57411827; called by muse, mutect2, varscan2
- KMT2C | c.12673C>T p.R4225* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | catalogued as COSV51492233; called by muse, mutect2, varscan2
- MAGEB17 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1388945346; called by muse, mutect2, varscan2
- PCDHB16 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs781890693, COSV99501902; called by muse, mutect2, varscan2
- TAF4 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 11/150 reads (7%) | catalogued as COSV53334463; called by muse, mutect2
- TIA1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as rs1485829059, COSV57008514; called by muse, mutect2, varscan2
- TRABD | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.284); catalogued as rs1484740738; called by muse, mutect2
- TRAM1L1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs762544664, COSV60292194; called by muse, mutect2, varscan2
- GPR152 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHDC4 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- MAN1A1 | c.1289A>C p.D430A | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MT1X | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NF1 | c.1900_1901dup p.P635Ffs*54 | Frame Shift Ins (INS) | VAF 89/369 reads (24%) | called by mutect2, pindel, varscan2
- OPRK1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OSBPL3 | c.2053A>T p.K685* | Nonsense Mutation (SNP) | VAF 34/195 reads (17%) | called by muse, mutect2, varscan2
- PSMD14 | c.764A>C p.Y255S | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- UBR4 | c.10619T>C p.V3540A | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ZNF727 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZSCAN18 | c.709_711del p.E237del | In Frame Del (DEL) | VAF 14/41 reads (34%) | called by pindel, varscan2
- CRLF2 | c.636C>T p.G212= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs752540078; called by muse, varscan2
- HDAC5 | c.264G>A p.Q88= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs761424626; called by muse, varscan2
- KY | c.696C>T p.F232= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as rs1181080791, COSV71016604; called by muse, mutect2, varscan2
- RP1L1 | c.1605G>A p.S535= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs200772091; ClinVar: benign; called by muse, mutect2, varscan2
- SPANXN3 | c.252G>A p.E84= | Silent (SNP) | VAF 8/145 reads (6%) | catalogued as COSV65140900; called by muse, mutect2
- TBX18 | c.174C>T p.G58= | Silent (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- AGAP6 | c.223+386T>G | Intron (SNP) | VAF 32/182 reads (18%) | called by muse, mutect2, varscan2
- FAM193B | c.1275+954C>G | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as rs758421881; called by muse, mutect2, varscan2
- IDS | c.-12G>A | 5'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2
- KIF5B | c.*2C>T | 3'UTR (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
